FM case AD1441 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Bladder.
https://portal.gdc.cancer.gov/cases/66cec7b4-f0e2-43eb-993e-2e8c893803ea

Female, 36.5 years: Squamous cell carcinoma, NOS (ICD-O-3 8070/3) of the bladder; metastasis biopsied or resected from the pelvis. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Metastatic.
